Gene-level copy-number profile of tumor specimen TCGA-UY-A78O-01A from TCGA case TCGA-UY-A78O, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.6 years (27,234 days).
Specimen TCGA-UY-A78O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.54004943-2485-428b-85df-3a6abe349b43.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A78O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a456b33-e69f-42d2-9ee2-9b2fe822c2fd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 286; copy number 2: 1,558; copy number 3: 26,108; copy number 4: 26,449; copy number 5: 2,917; copy number 6: 1,821; copy number 7: 377; copy number 15: 59; copy number 20: 101; copy number 22: 66; copy number 27: 7; copy number 28: 5; copy number 52: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A78O-01A-12D-A338-01): tumor purity 0.76, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:23,385,783–25,418,082, 34 genes (within-gene range 0–2): ENTPD4, AC104561.1, AC104561.2, AC104561.4, AC104561.3, SLC25A37, RNU4-71P, SINHCAFP3, NKX3-1, NKX2-6, AC012574.1, AC012574.2, AC012119.2, AC012119.1, STC1, RNU1-148P, AC023202.1, ADAM28, AC120193.1, ADAMDEC1, ADAM7, AC024958.1, AF106564.1, NEFM, NEFL, MIR6841, AC107373.2, AC107373.1, AC107373.3, AC073581.1, AC041005.1, DOCK5, AC091185.2, MIR6876.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 259 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,952,788–15,142,157, 66 genes, copy number 22 (broad region; genes not listed).
- chr3:21,405,737–21,406,508, 1 gene, copy number 27: VENTXP7.
- chr3:21,542,789–21,579,959, 1 gene, copy number 27: ZNF385D-AS1.
- chr3:25,555,543–25,687,123, 5 genes, copy number 28: AC093416.1, TOP2B, AC093416.2, MIR4442, CRIP1P2.
- chr3:26,015,669–26,717,537, 5 genes, copy number 27: RPEP2, HMGB3P12, VENTXP4, AC099754.1, LRRC3B.
- chr8:97,644,184–104,256,094, 160 genes, copy number 15–20 (within-gene range 4–20) (broad region; genes not listed).
- chr11:69,048,932–69,819,416, 21 genes, copy number 52: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.

Autosomal genes at a single copy (total copy number 1): 279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
